Somatic mutation profile of tumor specimen MP2PRT-PAVJBD-TMP1-A (aliquot MP2PRT-PAVJBD-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVJBD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,649 days).
Specimen MP2PRT-PAVJBD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41eb0266-7393-42b1-b943-41a34f791b7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJBD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJBD-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56eb6790-0169-48ac-87e5-849749dcf370

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 96/343 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADH1A | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763462785, COSV99265885; called by muse, mutect2, varscan2
- DCAF12L2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 51/823 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV63583920; called by muse, mutect2
- GRM5 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 113/427 reads (26%) | catalogued as COSV59603338, COSV59609677; called by muse, mutect2, varscan2
- KCND2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 162/334 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377746178, COSV58567964; called by muse, mutect2, varscan2
- LTBP1 | c.2959G>A p.G987R (on ENST00000404816 / NM_206943.4; = p.G661R on NM_000627.4) | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1025326290; called by muse, mutect2
- NOTCH3 | c.5938G>A p.A1980T | Missense Mutation (SNP) | VAF 49/399 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367885841; called by muse, varscan2
- RET | c.2716G>A p.V906M | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200627072, COSV60693919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELOA2 | c.2144G>A p.S715N | Missense Mutation (SNP) | VAF 143/749 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD17B7 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- LRATD1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 68/558 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SLC44A3 | c.1621G>T p.V541L (on ENST00000271227 / NM_001114106.3; = p.V493L on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- SMIM41 | c.269A>T p.D90V | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- TDRD6 | c.289T>G p.F97V | Missense Mutation (SNP) | VAF 286/988 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TLR4 | c.2057_2059dup p.D686_W687insY (on ENST00000355622 / NM_138554.5; = p.D646_W647insY on NM_003266.4) | In Frame Ins (INS) | VAF 120/277 reads (43%) | called by mutect2, pindel, varscan2
- BPIFB4 | c.645T>C p.G215= | Silent (SNP) | VAF 23/433 reads (5%) | catalogued as COSV64951339; called by muse, mutect2
- GRIA2 | c.1557C>T p.L519= | Silent (SNP) | VAF 80/355 reads (23%) | catalogued as COSV52395909; called by muse, mutect2, varscan2
- HK3 | c.2097G>T p.V699= | Silent (SNP) | VAF 104/365 reads (28%) | called by muse, mutect2, varscan2
- RIMS1 | c.321C>T p.G107= | Silent (SNP) | VAF 96/522 reads (18%) | catalogued as rs1408660383, COSV53462605; called by muse, mutect2, varscan2
